Gene-level copy-number profile of tumor specimen C3N-00223-01 from CPTAC case C3N-00223, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.5 years (25,368 days).
Specimen C3N-00223-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file db2333ec-c1c0-41bc-88b5-fbbe336fc3aa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00223-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/50677773-ac40-487b-87a5-305e47c1159e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22; copy number 2: 57,313; copy number 3: 664; copy number 4: 245; copy number 5: 141; copy number 6: 17; copy number 7: 1; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 160 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene, copy number 6: AC239798.1.
- chr1:143,874,793–143,905,966, 3 genes, copy number 5 (within-gene range 2–5): FCGR1CP, H2BP2, H3-2.
- chr1:188,508,538–188,695,111, 3 genes, copy number 5: AL929288.1, AL929288.2, RPS3AP9.
- chr1:190,097,658–190,478,404, 2 genes, copy number 5: BRINP3, AL354771.1.
- chr1:198,523,222–199,393,307, 15 genes, copy number 5 (within-gene range 4–5): ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16.
- chr1:244,653,103–245,709,432, 16 genes, copy number 6 (within-gene range 3–7): DESI2, AL451007.1, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8.
- chr8:127,072,694–127,227,541, 1 gene, copy number 5 (within-gene range 4–5): CASC19.
- chr8:127,289,817–128,564,679, 20 genes, copy number 5: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:129,241,228–129,291,275, 3 genes, copy number 5: AC103833.2, AC103833.1, RN7SKP206.
- chr8:135,859,369–137,105,458, 2 genes, copy number 7–8: LINC02055, RNU6-144P.
- chr20:62,796,473–64,327,972, 94 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
